Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0CM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0CM-01A (Primary Tumor).

[page 1 of 2]
PERSONAL DATA - PRIVACY ACT OF 1974

SURGICAL PATHOLOGY REPORT

Patient: Specimen #:
FMP/SSN:
DOB/Age/Sex: Race: BLACK Taken:
Location: Received:
Physician(s): Reported:

****AMENDED**** 1CB-0-3

SPECIMEN: LEFT BREAST MASS

*Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 1/24/11 per*

=====

FINAL DIAGNOSIS:

BREAST, LEFT, BIOPSY:

POORLY DIFFERENTIATED INVASIVE DUCTAL CARCINOMA (GRADE III/III PER
MODIFIED BLOOM RICHARDSON GRADING) WITH EXTENSIVE NECROSIS.

TUMOR SIZE = 3.0 CM (MEASURED GROSSLY).

MINIMAL IN-SITU COMPONENT (HIGH GRADE).

LYMPHVASCULAR SPACE INVASION IS IDENTIFIED.

TUMOR EXTENDS TO WITHIN 1 MM OF THE DEEP SURGICAL MARGIN.

HYALINIZED FIBROADENOMA.

COMMENT:

Dr. was notified of the above diagnosis via e-mail on

ESTROGEN AND PROGESTERONE RECEPTORS WERE PERFORMED. THE TUMOR IS NEGATIVE
FOR ESTROGEN RECEPTORS AND FOCALLY POSITIVE FOR PROGESTERONE RECEPTORS.

HER2/neu BY IMMUNOHISTOCHEMISTRY (HERCEPTEST): NEGATIVE (0+).

**** Report Electronically Signed Out ****

=====

CLINICAL DIAGNOSIS AND HISTORY:

{None Given}

GROSS DESCRIPTION:

LEFT BREAST MASS received fresh and consists of a fibrofatty tissue
fragment measuring 8.0 x 2.5 x 2.3 cm. The deep margin is designated with
a suture. The deep margin is inked black, while the remainder of the
specimen is inked blue. At the deep margin there is a firm,
well-circumscribed mass measuring 3.0 x 2.5 x 2.5 cm with a tan, gritty,
and focally hemorrhagic cut surface. The remaining tissue is predominantly

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

fatty and unremarkable. Multiple sections of tumor and grossly normal breast tissue are harvested for CBCP protocol. Mirror images for histology are as follows:

A1-Tumor.

A2-Tumor.

A3-Gross normal.

Additional sections are as follows:

A4-10-Tumor.

A11-12-Gross normal.

Source: NCI Genomic Data Commons file df558174-cd36-4d74-98d4-1013409d0b8d (TCGA-A2-A0CM.2972AB07-2C29-43B8-96DA-1386C5E248EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).